Somatic mutation profile of tumor specimen TCGA-13-1484-01A (aliquot TCGA-13-1484-01A-01W-0545-08) from TCGA case TCGA-13-1484, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.1 years (22,698 days).
Specimen TCGA-13-1484-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed2887e2-d471-42a8-86e6-aa39dfedeecc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1484-10A (Blood Derived Normal), aliquot TCGA-13-1484-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32fae5c3-22d7-4d2c-9ea6-8d3ecb4deb12

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.700T>A p.Y234N | Missense Mutation (SNP) | VAF 184/430 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs864622237, CM137618, COSV52694920, COSV52730114, COSV52730255; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99933534; called by muse, mutect2
- ANXA7 | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65823207; called by muse, mutect2, varscan2
- ARAP3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 94/431 reads (22%) | catalogued as COSV53349576; called by muse, mutect2, varscan2
- CDH10 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100051611; called by muse, mutect2, varscan2
- CES3 | c.1027G>T p.V343F | Missense Mutation (SNP) | VAF 154/655 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV57592983; called by muse, mutect2, varscan2
- CGNL1 | c.186del p.C63Afs*2 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | catalogued as COSV55565304; called by mutect2, pindel, varscan2
- COL6A3 | c.8028C>G p.D2676E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.807); catalogued as COSV55084098; called by muse, mutect2, varscan2
- CRNN | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 216/2109 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55121296; called by muse, mutect2, varscan2
- CRTAC1 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 17/208 reads (8%) | catalogued as rs754081759, COSV53999129; called by muse, mutect2
- DAXX | c.2009C>A p.P670H | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99802150; called by muse, mutect2
- EFTUD2 | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV99493960; called by muse, mutect2, varscan2
- FTMT | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs1222072712, COSV58420066; called by muse, mutect2, varscan2
- FZD5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54943196; called by muse, mutect2, varscan2
- GET3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs368392204; called by muse, mutect2, varscan2
- HHLA2 | c.716T>A p.V239D | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63316381; called by muse, mutect2, varscan2
- KANSL1L | c.1707C>G p.H569Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.022); catalogued as COSV55990546; called by muse, mutect2, varscan2
- KCNH5 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1313204598, COSV59753452; called by muse, mutect2, varscan2
- LCOR | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63630479; called by muse, mutect2, varscan2
- LRFN5 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs548468008, COSV53243796; called by muse, mutect2
- MBD3 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs548368623, COSV50083180, COSV50085515; called by muse, mutect2, varscan2
- NDUFB7 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53107970; called by muse, mutect2, varscan2
- NUTM1 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.674); catalogued as COSV59216200; called by muse, mutect2, varscan2
- OR4A47 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs370946107; called by muse, varscan2
- OR51V1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405336209, COSV100343181, COSV58314148; called by muse, mutect2
- PLCH2 | c.1278C>G p.I426M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); catalogued as COSV53940572; called by muse, mutect2, varscan2
- RRP12 | c.560T>A p.F187Y | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV59666184; called by muse, mutect2, varscan2
- SHPRH | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51606522; called by muse, mutect2, varscan2
- STN1 | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV56544381, COSV99830299; called by muse, mutect2, varscan2
- SYNGAP1 | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as COSV53379465; called by muse, mutect2, varscan2
- TAT | c.1037T>G p.L346R | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63532518; called by muse, mutect2, varscan2
- TFAP2D | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 44/505 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50411015, COSV99147218; called by muse, mutect2
- TTN | c.54383C>T p.A18128V (on ENST00000591111; = p.A10704V on NM_003319.4) | Missense Mutation (SNP) | VAF 73/278 reads (26%) | PolyPhen possibly damaging (0.814); catalogued as COSV59954877; called by muse, mutect2, varscan2
- USP29 | c.831C>A p.D277E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV54141114; called by muse, mutect2, varscan2
- WNT6 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.195); catalogued as COSV52109663; called by muse, mutect2, varscan2
- CABP4 | c.691C>T p.L231= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV57797559; called by muse, mutect2, varscan2
- CASS4 | c.2043G>A p.G681= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV64385710, COSV64385928; called by muse, mutect2
- CPXM2 | c.930C>T p.T310= | Silent (SNP) | VAF 43/284 reads (15%) | catalogued as COSV99582359; called by muse, mutect2, varscan2
- DNAAF5 | c.1899G>A p.L633= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs1460105075, COSV52415331; called by muse, mutect2, varscan2
- ITFG1 | c.1254A>G p.G418= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV57745873; called by muse, mutect2, varscan2
- KIAA1549L | c.2076C>T p.A692= (on ENST00000321505; = p.A989= on NM_012194.3) | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs531225970, COSV55771276; called by muse, mutect2, varscan2
- NTRK1 | c.1653G>A p.E551= | Silent (SNP) | VAF 44/257 reads (17%) | catalogued as COSV62324446; called by muse, mutect2, varscan2
- PPRC1 | c.174G>A p.A58= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs574814323, COSV53384126; called by muse, mutect2, varscan2
- PRAMEF14 | c.717C>T p.F239= | Silent (SNP) | VAF 20/502 reads (4%) | called by muse, mutect2
- PTCHD1 | c.2142G>T p.S714= | Silent (SNP) | VAF 55/178 reads (31%) | catalogued as COSV101037624, COSV65059489; called by muse, mutect2, varscan2
- SEPTIN9 | c.1092A>T p.P364= (on ENST00000427177 / NM_001113491.2; = p.P346= on NM_006640.4) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV61203188; called by muse, mutect2, varscan2
- SLC37A2 | c.597C>A p.A199= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV53521316; called by muse, mutect2, varscan2
- TRRAP | c.7836C>T p.S2612= (on ENST00000359863 / NM_001244580.1; = p.S2594= on NM_003496.3) | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as rs1433071532, COSV62841590; called by muse, mutect2, varscan2
- FAM184A | c.1815+281C>T | Intron (SNP) | VAF 25/110 reads (23%) | catalogued as COSV100137842; called by muse, mutect2, varscan2
